CCDI case PBBLUN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/32fc1c6d-003c-4c06-9dd8-e118f65bad27

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic fibroma: ICD-O-3 morphology code: 8823/0; Tissue or organ of origin: Pleura, NOS; Age at diagnosis: 8.1 years (2,948 days).

Biospecimens (3 samples)
- Sample 0DBW3S: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBW3Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBW4F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
